Gene-level copy-number profile of tumor specimen TCGA-KQ-A41R-01A from TCGA case TCGA-KQ-A41R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 80.4 years (29,351 days).
Specimen TCGA-KQ-A41R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.71f5f22a-4c59-44c6-94e3-bcbac255cda1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KQ-A41R-10G (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b585f683-777a-4330-9761-f142515578a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 1,684; copy number 3: 20,713; copy number 4: 24,071; copy number 5: 8,394; copy number 6: 2,762; copy number 7: 56; copy number 8: 1,964; copy number 10: 43; copy number 12: 39; copy number 14: 70; copy number 18: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KQ-A41R-01A-21D-A34T-01): tumor purity 0.71, ploidy 4.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 163 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:158,795,317–163,736,012, 70 genes, copy number 14 (broad region; genes not listed).
- chr6:14,391,094–15,663,058, 16 genes, copy number 12–18: AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P, 5S_rRNA, DTNBP1, AL021978.1.
- chr6:19,143,695–21,602,383, 33 genes, copy number 12: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:21,822,536–21,822,737, 1 gene, copy number 12: AL136313.1.
- chr22:19,846,138–20,495,844, 43 genes, copy number 10: RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
